Gene-level copy-number profile of tumor specimen TCGA-D8-A1JE-01A from TCGA case TCGA-D8-A1JE, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.1 years (22,683 days).
Specimen TCGA-D8-A1JE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.ff8bc49a-9c34-45ab-864b-0e052fd6e594.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D8-A1JE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8f7df6f7-8bb0-4f94-ac9a-34babf81ce7f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 3: 25,085; copy number 4: 229; copy number 5: 143; copy number 6: 18,020; copy number 7: 2,249; copy number 8: 13,425; copy number 11: 9; copy number 12: 129; copy number 13: 110; copy number 14: 415.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D8-A1JE-01A-11D-A13J-01): tumor purity 0.55, ploidy 2.82, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 16,337 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–248,919,946, 2,498 genes, copy number 8 (broad region; genes not listed).
- chr5:58,198–181,342,213, 2,985 genes, copy number 8 (broad region; genes not listed).
- chr7:57,599,794–62,275,678, 23 genes, copy number 7: NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr9:14,475–21,638,676, 306 genes, copy number 14 (broad region; genes not listed).
- chr9:33,290,512–35,736,999, 130 genes, copy number 11–12 (within-gene range 4–12) (broad region; genes not listed).
- chr9:38,804,007–138,203,325, 1,659 genes, copy number 8–13 (broad region; genes not listed).
- chr10:28,743,506–28,941,910, 1 gene, copy number 7 (within-gene range 3–7): LINC01517.
- chr10:28,874,393–133,761,125, 1,834 genes, copy number 7 (broad region; genes not listed).
- chr12:24,704,503–133,214,832, 2,411 genes, copy number 8–14 (broad region; genes not listed).
- chr13:18,467,172–27,488,232, 234 genes, copy number 8 (broad region; genes not listed).
- chr13:28,820,348–29,505,947, 3 genes, copy number 14 (within-gene range 3–14): MTUS2, MTUS2-AS2, GAPDHP69.
- chr16:11,555–35,912,516, 1,419 genes, copy number 7–8 (broad region; genes not listed).
- chr20:87,250–64,313,132, 1,458 genes, copy number 8 (broad region; genes not listed).
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
